Gene-level copy-number profile of tumor specimen TCGA-CG-4444-01A from TCGA case TCGA-CG-4444, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,912 days).
Specimen TCGA-CG-4444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.14a43e9c-d73d-440a-9597-7e9d6f6e34df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4444-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7c04aaef-ba8f-4a97-94da-a9c37490d878

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 284; copy number 2: 4,617; copy number 3: 22,814; copy number 4: 18,711; copy number 5: 5,997; copy number 6: 3,922; copy number 7: 1,120; copy number 8: 369; copy number 9: 1,082; copy number 10: 39; copy number 11: 152; copy number 12: 137; copy number 14: 152; copy number 15: 48; copy number 16: 145; copy number 17: 42; copy number 18: 49; copy number 20: 45; copy number 23: 7; copy number 28: 39; copy number 31: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4444-01A-01D-1155-01): tumor purity 0.49, ploidy 3.93, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:62,672,285–62,796,714, 1 gene: LINC00448.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,158 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,706,901–24,556,024, 28 genes, copy number 8: ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1, IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT.
- chr1:24,563,627–24,563,974, 1 gene, copy number 8: AL445686.1.
- chr1:143,343,180–154,220,637, 482 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr6:134,343,307–138,344,663, 75 genes, copy number 16 (broad region; genes not listed).
- chr8:69,922,751–76,683,308, 111 genes, copy number 12–28 (broad region; genes not listed).
- chr8:76,733,302–76,733,476, 1 gene, copy number 12: AC011716.1.
- chr8:76,966,768–86,154,225, 139 genes, copy number 8–23 (within-gene range 5–23) (broad region; genes not listed).
- chr8:90,001,405–100,559,784, 194 genes, copy number 7–17 (within-gene range 5–18) (broad region; genes not listed).
- chr8:102,417,979–104,589,024, 52 genes, copy number 9 (within-gene range 3–9): AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1, DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2.
- chr8:117,520,713–128,564,679, 172 genes, copy number 10–31 (broad region; genes not listed).
- chr9:11,313,397–12,288,238, 5 genes, copy number 28 (within-gene range 1–28): AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1.
- chr9:22,446,824–26,118,408, 25 genes, copy number 8–15: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:31,644,576–36,830,456, 198 genes, copy number 9–28 (broad region; genes not listed).
- chr10:49,014,236–52,314,507, 56 genes, copy number 9–15 (within-gene range 3–15): VSTM4, FAM170B-AS1, FAM170B, TMEM273, C10orf71-AS1, C10orf71, DRGX, AL138760.1, ERCC6, HMGB1P50, CHAT, SLC18A3, C10orf53, OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1.
- chr10:66,079,243–66,118,326, 1 gene, copy number 10: AC022017.1.
- chr10:70,815,948–79,826,594, 208 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:128,095,758–129,860,003, 25 genes, copy number 8 (within-gene range 4–8): LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B.
- chr12:11,541,395–13,982,002, 57 genes, copy number 8 (within-gene range 6–8): AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1, EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.
- chr12:46,183,063–48,230,275, 68 genes, copy number 8 (broad region; genes not listed).
- chr12:61,231,159–84,672,026, 366 genes, copy number 7 (broad region; genes not listed).
- chr12:121,887,540–122,422,632, 20 genes, copy number 8: AC069503.5, PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P, CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1.
- chr14:21,918,188–22,531,138, 100 genes, copy number 9 (broad region; genes not listed).
- chr14:33,597,057–41,149,309, 126 genes, copy number 7 (broad region; genes not listed).
- chr15:57,953,424–58,749,791, 18 genes, copy number 8 (within-gene range 6–8): ALDH1A2, AC012653.1, AC012653.2, AC025431.1, AQP9, MTCO3P23, MTND3P12, AC066616.2, MTND5P32, MTCYBP23, AC066616.1, LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1, ADAM10.
- chr15:59,132,434–59,372,871, 1 gene, copy number 10 (within-gene range 6–10): MYO1E.
- chr15:59,266,720–59,873,495, 19 genes, copy number 10: AC092756.1, RNU6-212P, AC092868.2, FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.2, AC092079.1.
- chr15:68,483,202–74,756,607, 157 genes, copy number 7–9 (broad region; genes not listed).
- chr15:88,252,730–93,760,886, 170 genes, copy number 10–17 (broad region; genes not listed).
- chr15:93,825,058–93,825,159, 1 gene, copy number 12: AC103996.1.
- chr17:38,601,049–38,996,624, 30 genes, copy number 9: AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2.
- chr19:27,638,483–31,147,981, 70 genes, copy number 8–11 (broad region; genes not listed).
- chr20:20,659,710–30,816,274, 182 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 196. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
